Somatic mutation profile of tumor specimen ALCH-B385-TTP1-A (aliquot ALCH-B385-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B385, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.9 years (24,453 days).
Specimen ALCH-B385-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26071312-817c-49d4-984e-9aec4cf734a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B385-NB1-A (Blood Derived Normal), aliquot ALCH-B385-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c64ff93-6254-4838-86af-93bd645d3d07

The open-access MAF lists 117 somatic variants for this specimen: 77 protein-altering or splice-affecting, 28 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 28, Intron 8, Frame Shift Del 5, Splice Region 5, 3'UTR 2, Nonsense Mutation 2, 5'Flank 1, In Frame Ins 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 28/96 reads (29%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BAP1 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 217/481 reads (45%) | catalogued as COSV56230983, COSV99964778; called by muse, mutect2, varscan2
- BRINP3 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66526222; called by muse, mutect2, varscan2
- CEP104 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs949661853; called by muse, mutect2
- CILP | c.2737C>T p.R913W | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139235879, COSV56022909; called by muse, mutect2, varscan2
- CRACD | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs746463472, COSV51731992; called by muse, mutect2, varscan2
- EARS2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs549058278, CM165150, COSV71942926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF2K | c.1922A>G p.Y641C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99532980; called by muse, varscan2
- EPHB2 | c.1943T>A p.I648N (on ENST00000400191 / NM_001309193.2; = p.I649N on NM_004442.7) | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as rs781301341; called by muse, mutect2, varscan2
- FAT2 | c.9278G>A p.R3093Q | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as rs557505076, COSV55829385; called by muse, mutect2, varscan2
- FILIP1 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs755925479, COSV52727083; called by muse, mutect2, varscan2
- GABRB1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs751931636, COSV54974645; called by muse, mutect2, varscan2
- GAPT | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs370924428; called by muse, mutect2
- GTF2H1 | c.1270A>G p.S424G | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs1439509684; called by muse, varscan2
- HAS1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs948729841, COSV55788302; called by muse, mutect2, varscan2
- HECW1 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs374489291; called by muse, mutect2, varscan2
- HTR1B | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs200726002, COSV100885493, COSV64052020; called by muse, mutect2, varscan2
- IGHV1-58 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as rs782712844; called by muse, mutect2, varscan2
- ISG15 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs750338976; called by muse, mutect2, varscan2
- JPH2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV65905586; called by muse, mutect2, varscan2
- LAMC3 | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV62653834; called by muse, mutect2, varscan2
- LGI1 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV65057438; called by muse, mutect2, varscan2
- MON2 | c.4429G>T p.A1477S | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV54816314; called by muse, mutect2, varscan2
- MYT1 | c.2675+4C>T | Splice Region (SNP) | VAF 44/217 reads (20%) | catalogued as rs780792496; called by muse, mutect2, varscan2
- OR10T2 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57780708; called by muse, varscan2
- OR2M4 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756695074, COSV60707084; called by muse, mutect2, varscan2
- PCDHB5 | c.1504del p.L502Wfs*39 | Frame Shift Del (DEL) | VAF 487/1017 reads (48%) | catalogued as COSV50650291, COSV99039329; called by mutect2, pindel, varscan2
- PHYHIP | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.555); catalogued as rs746137577, COSV58688288; called by muse, mutect2, varscan2
- POU2F2 | c.187-7C>T | Splice Region (SNP) | VAF 38/76 reads (50%) | catalogued as rs1176286728; called by muse, mutect2, varscan2
- SLC9A5 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766839108, COSV55363364, COSV55365291; called by muse, mutect2, varscan2
- SLIT3 | c.2491C>T p.H831Y | Missense Mutation (SNP) | VAF 72/357 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60598122; called by muse, mutect2, varscan2
- SNTG1 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); catalogued as rs748623742; called by muse, mutect2, varscan2
- ST8SIA3 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 51/208 reads (25%) | PolyPhen benign (0.007); catalogued as rs373560582; called by muse, mutect2, varscan2
- TAF5 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs751144325; called by muse, mutect2, varscan2
- TRIP12 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52262190; called by muse, mutect2
- TRPA1 | c.1292A>T p.N431I | Missense Mutation (SNP) | VAF 72/680 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV100083131, COSV51562790; called by muse, mutect2, varscan2
- TUBA1B | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 118/678 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.533); catalogued as COSV60137023; called by muse, mutect2, varscan2
- UQCRC1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs376087580; called by muse, mutect2, varscan2
- ZNF385D | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1419009725; called by muse, mutect2, varscan2
- ZNF799 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as rs1345073796; called by muse, mutect2, varscan2
- ANXA10 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ARHGAP6 | c.622A>C p.S208R | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- BRINP3 | c.1698G>C p.E566D | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CDC14C | c.1589T>A p.V530E (on ENST00000428251; = p.V423E on NM_152627.3) | Missense Mutation (SNP) | VAF 21/625 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2
- CNTNAP4 | c.1494C>A p.D498E | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL22A1 | c.4550del p.M1517Rfs*19 | Frame Shift Del (DEL) | VAF 39/209 reads (19%) | called by mutect2, pindel, varscan2
- DKC1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 111/669 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FAR1 | c.225del p.F75Lfs*6 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- GRAMD1B | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HHLA1 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 80/769 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- HOOK3 | c.142A>C p.I48L | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IL19 | c.281_282del p.Q94Rfs*48 | Frame Shift Del (DEL) | VAF 47/272 reads (17%) | called by mutect2, pindel, varscan2
- KLHL9 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMC1 | c.4648A>C p.K1550Q | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIN28B | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- MRPS6 | c.376T>C p.*126Rext*46 | Nonstop Mutation (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- MUC4 | c.11623G>T p.V3875F | Missense Mutation (SNP) | VAF 170/575 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MYO5A | c.4207C>A p.H1403N | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- NSL1 | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- OR7D4 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.215C>A p.T72K (on ENST00000259318 / NM_001136562.3; = p.T303K on NM_007203.5) | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PDE9A | c.1154A>T p.H385L | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN3 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- RB1CC1 | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- RPS6KA4 | c.127+3G>C | Splice Region (SNP) | VAF 62/169 reads (37%) | called by muse, mutect2, varscan2
- RYR1 | c.10827C>T p.T3609= | Splice Region (SNP) | VAF 105/372 reads (28%) | called by muse, mutect2, varscan2
- SLC35B1 | c.14del p.P5Rfs*22 | Frame Shift Del (DEL) | VAF 39/158 reads (25%) | called by mutect2, pindel, varscan2
- SLC8A1 | c.2762A>C p.N921T | Missense Mutation (SNP) | VAF 261/451 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STEAP4 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TERF1 | c.1249A>T p.S417C (on ENST00000276603 / NM_017489.3; = p.S397C on NM_003218.4) | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TESK2 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 106/721 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TLN2 | c.7035G>T p.Q2345H | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TLR4 | c.2398A>T p.S800C (on ENST00000355622 / NM_138554.5; = p.S760C on NM_003266.4) | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- UBXN2B | c.133A>C p.K45Q | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS13B | c.11230C>G p.P3744A | Missense Mutation (SNP) | VAF 129/473 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZAN | c.4098G>A p.E1366= | Splice Region (SNP) | VAF 70/190 reads (37%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8528A>T p.K2843I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- ABCC12 | c.2418T>A p.I806= | Silent (SNP) | VAF 56/333 reads (17%) | catalogued as rs76822180; called by muse, mutect2, varscan2
- AFF1 | c.1902C>T p.S634= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- C17orf75 | c.633T>A p.L211= | Silent (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- CADM3 | c.1068C>T p.I356= (on ENST00000368125 / NM_001127173.3; = p.I390= on NM_021189.5) | Silent (SNP) | VAF 149/443 reads (34%) | called by muse, mutect2, varscan2
- CLRN2 | c.456C>T p.I152= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as rs369026851; called by muse, mutect2
- DGKH | c.3195A>G p.L1065= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- DPYS | c.579G>A p.A193= | Silent (SNP) | VAF 58/648 reads (9%) | catalogued as rs188038278, COSV60906586; called by muse, mutect2
- EHBP1L1 | c.4263G>A p.R1421= | Silent (SNP) | VAF 54/280 reads (19%) | catalogued as rs1478197953; called by muse, mutect2, varscan2
- FAM135B | c.468C>T p.F156= | Silent (SNP) | VAF 44/518 reads (8%) | catalogued as rs747361698, COSV50526251; called by muse, mutect2
- FAM160A2 | c.1314G>A p.P438= | Silent (SNP) | VAF 61/390 reads (16%) | catalogued as rs375612041; called by muse, mutect2, varscan2
- HTR2C | c.648T>C p.L216= | Silent (SNP) | VAF 63/195 reads (32%) | catalogued as COSV99349004; called by muse, mutect2, varscan2
- MAGEA6 | c.918G>A p.E306= | Silent (SNP) | VAF 58/230 reads (25%) | catalogued as rs782447043, COSV61449108; called by muse, varscan2
- PCDH17 | c.30T>G p.L10= | Silent (SNP) | VAF 65/385 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.2382G>A p.S794= | Silent (SNP) | VAF 81/463 reads (17%) | called by muse, mutect2, varscan2
- PIGO | c.2319T>G p.A773= | Silent (SNP) | VAF 53/267 reads (20%) | called by muse, mutect2, varscan2
- PIK3C2G | c.702A>G p.L234= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- PLAC1 | c.261C>G p.V87= | Silent (SNP) | VAF 28/227 reads (12%) | catalogued as rs935668324; called by muse, mutect2, varscan2
- PLK3 | c.984C>T p.C328= | Silent (SNP) | VAF 33/229 reads (14%) | catalogued as rs137889208; called by muse, mutect2, varscan2
- RAB40A | c.618G>A p.V206= | Silent (SNP) | VAF 26/458 reads (6%) | called by muse, mutect2
- RARS1 | c.495C>T p.H165= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99199265; called by muse, mutect2, varscan2
- RGL2 | c.1971G>A p.E657= | Silent (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- RPRD1B | c.411C>T p.P137= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs758478465, COSV65032332; called by muse, mutect2, varscan2
- RYR2 | c.12720G>A p.T4240= | Silent (SNP) | VAF 117/736 reads (16%) | catalogued as rs774851947, COSV100769352, COSV63665080; called by muse, mutect2, varscan2
- SERPINA1 | c.18G>A p.S6= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as rs1343069141, COSV63345289; called by muse, mutect2, varscan2
- SLC7A1 | c.1020C>T p.A340= | Silent (SNP) | VAF 37/192 reads (19%) | catalogued as rs550186121; called by muse, mutect2, varscan2
- ZGRF1 | c.2676A>G p.K892= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- ZNF717 | c.747A>T p.S249= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- ZNF784 | c.642C>T p.H214= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs534046610, COSV57595343; called by muse, varscan2
- ARX | c.-28C>A | 5'UTR (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- CLASP2 | c.2351-929C>T | Intron (SNP) | VAF 80/184 reads (43%) | called by muse, mutect2, varscan2
- FXYD2 | c.139+16T>C | Intron (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- HSD3B2 | c.*5A>G | 3'UTR (SNP) | VAF 78/312 reads (25%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1023+25C>A | Intron (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- MAMLD1 | c.*218G>C | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- PEMT | c.356-39G>A | Intron (SNP) | VAF 37/153 reads (24%) | called by muse, mutect2, varscan2
- RPLP2 | c.172+147G>T | Intron (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- SEC14L1 | c.2042+32G>A | Intron (SNP) | VAF 26/111 reads (23%) | catalogued as rs778956279; called by muse, mutect2, varscan2
- SH3KBP1 | c.1298+58G>T | Intron (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1298+57G>T | Intron (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- SNORD114-31 | chr14:100990174 T>C | 5'Flank (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
